Somatic mutation profile of tumor specimen TCGA-94-7033-01A (aliquot TCGA-94-7033-01A-11D-1945-08) from TCGA case TCGA-94-7033, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.8 years (26,948 days).
Specimen TCGA-94-7033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f78bf6cf-f985-473a-a335-759b53abea21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-7033-10A (Blood Derived Normal), aliquot TCGA-94-7033-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f11a213-9930-469c-9e2b-f6ee36a038ee

The open-access MAF lists 134 somatic variants for this specimen: 106 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 26, Nonsense Mutation 5, In Frame Del 4, Frame Shift Del 2, Nonstop Mutation 2, 5'UTR 1, Splice Site 1, 5'Flank 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223408, CM051001, CM082472, COSV101188037; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BRCA2 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs80358913, COSV101204525; ClinVar: pathogenic; called by muse, varscan2
- FLCN | c.189del p.A64Qfs*66 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs876660611; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1064796886, CM131938, COSV64289920, COSV64290011, COSV64297199; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ACAN | c.89G>C p.S30T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100718822; called by muse, mutect2, varscan2
- ACSL1 | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV99860834; called by muse, mutect2, varscan2
- ACTB | c.1102T>G p.S368A | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100079830, COSV99045515; called by muse, mutect2, varscan2
- ADAD2 | c.882G>C p.L294= (on ENST00000315906 / NM_001145400.2; = p.L376= on NM_139174.4) | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99235497; called by muse, mutect2, varscan2
- ADAL | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99980174; called by muse, mutect2, varscan2
- ADAM19 | c.1130+1G>A p.X377_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57429831, COSV99977956; called by muse, varscan2
- ADAMTS20 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs368915817, COSV101240640; called by muse, mutect2
- ADCK1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as rs199682998; called by muse, mutect2, varscan2
- ADGRL2 | c.4374T>A p.S1458R (on ENST00000370717 / NM_001366005.1; = p.S1402R on NM_012302.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99590557; called by muse, mutect2, varscan2
- AGO1 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100940882, COSV64595284; called by muse, mutect2, varscan2
- ALDH3B2 | c.1040G>C p.C347S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV100824096; called by muse, mutect2, varscan2
- ANK2 | c.10206A>T p.K3402N | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100003156; called by muse, mutect2, varscan2
- APRT | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99243363; called by muse, mutect2, varscan2
- AQP9 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1566991205, COSV99583118; called by muse, mutect2, varscan2
- ASPM | c.6842G>C p.R2281T | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV99660850; called by muse, mutect2, varscan2
- ATG12 | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV57243572, COSV99174639; called by muse, mutect2, varscan2
- ATG2B | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV100738151; called by muse, mutect2
- ATP1A4 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100927612; called by muse, mutect2, varscan2
- BTBD17 | c.1012A>C p.S338R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100945377, COSV64729229; called by muse, mutect2
- BTBD7 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV100108108; called by muse, mutect2, varscan2
- CACNA1C | c.1161T>G p.S387R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100220861; called by muse, mutect2, varscan2
- CATSPER1 | c.1639G>C p.V547L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV100376139; called by muse, mutect2, varscan2
- CCT8L2 | c.1674G>C p.*558Yext*1 | Nonstop Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100742954; called by muse, mutect2
- CD1B | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939268; called by muse, mutect2, varscan2
- CD300A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV100177958; called by muse, mutect2, varscan2
- CDH16 | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV100234050; called by muse, mutect2, varscan2
- CHTOP | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as COSV100904698; called by muse, mutect2, varscan2
- CNTN5 | c.1838C>G p.P613R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.958); catalogued as COSV99679584; called by muse, mutect2, varscan2
- CPED1 | c.1829G>C p.G610A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as COSV100120826, COSV100121222; called by muse, mutect2, varscan2
- CTR9 | c.2774C>G p.T925S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100797413; called by muse, mutect2, varscan2
- CYCS | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99995079; called by muse, mutect2
- DLGAP1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV100232799; called by muse, mutect2, varscan2
- EHBP1L1 | c.2788C>G p.Q930E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499962; called by mutect2, varscan2
- EIF4G3 | c.2764G>T p.D922Y | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99945120; called by muse, mutect2, varscan2
- ENDOU | c.789G>C p.L263F (on ENST00000422538 / NM_001172439.2; = p.L222F on NM_006025.4) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99968352; called by muse, mutect2, varscan2
- ESYT2 | c.1090C>G p.R364G (on ENST00000613624; = p.R288G on NM_020728.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51748604; called by muse, mutect2, varscan2
- EXOC3L1 | c.1050G>C p.M350I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99333864; called by muse, mutect2, varscan2
- FAM81B | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99353080; called by muse, mutect2, varscan2
- FANCE | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.219); catalogued as COSV100003483; called by muse, mutect2, varscan2
- FAR2 | c.1071C>G p.H357Q | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99478736, COSV99479449; called by muse, mutect2, varscan2
- FBXO7 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.11); catalogued as COSV99832849; called by muse, mutect2, varscan2
- FLT4 | c.866C>G p.T289R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV99988180; called by muse, mutect2, varscan2
- GALNT6 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11169818, COSV100695587; called by muse, mutect2, varscan2
- GDNF | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100427516; called by muse, mutect2, varscan2
- GRIN2C | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as rs757807708, COSV99501264; called by muse, mutect2, varscan2
- HOXD8 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497135; called by muse, mutect2, varscan2
- HPS4 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV100404578; called by muse, mutect2, varscan2
- IBTK | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100091174; called by muse, varscan2
- IRF2BP2 | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100784368; called by muse, mutect2, varscan2
- KCNK2 | c.907G>A p.V303I (on ENST00000444842 / NM_001017425.3; = p.V288I on NM_014217.4) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.122); catalogued as COSV67208287; called by muse, mutect2, varscan2
- KCNMB3 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.096); catalogued as COSV99841319; called by muse, mutect2, varscan2
- MAEL | c.682A>T p.K228* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100774764; called by muse, mutect2, varscan2
- MCCC1 | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99659963; called by muse, mutect2
- MGME1 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV100891366; called by muse, mutect2, varscan2
- MIER1 | c.379G>T p.E127* (on ENST00000355356 / NM_001077701.3; = p.E144* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100591187, COSV62529899; called by muse, mutect2, varscan2
- MLEC | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772678315, COSV99949725; called by muse, mutect2, varscan2
- MTERF1 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100699586; called by muse, mutect2, varscan2
- MYH4 | c.5312A>C p.E1771A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99701875; called by muse, mutect2, varscan2
- NACC1 | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99457164; called by muse, mutect2, varscan2
- NBAS | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377409290; called by muse, mutect2, varscan2
- NLRP14 | c.2368T>C p.F790L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.497); catalogued as COSV100205268; called by muse, mutect2, varscan2
- NUP210L | c.4558C>G p.Q1520E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99668645; called by muse, mutect2, varscan2
- OR5F1 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99558827; called by muse, mutect2
- PCF11 | c.4615A>G p.I1539V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748059433, COSV100018929; called by muse, mutect2
- PGAP1 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100698309; called by muse, mutect2, varscan2
- PODN | c.1406T>A p.V469E (on ENST00000395871; = p.V421E on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100439721; called by muse, mutect2, varscan2
- POU6F2 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs1254379259, COSV101302790; called by muse, varscan2
- PTN | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100780974; called by muse, mutect2, varscan2
- RAP1GAP2 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV99623956; called by muse, mutect2, varscan2
- RASGRP4 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385093; called by muse, mutect2, varscan2
- RBM23 | c.893C>T p.S298L (on ENST00000359890 / NM_001077351.2; = p.S282L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as rs1432135378, COSV100321465; called by muse, mutect2, varscan2
- RNF217 | c.1235A>C p.E412A (on ENST00000521654 / NM_001286398.2; = p.E120A on NM_152553.5) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV99255230; called by muse, mutect2
- RTL9 | c.1025A>G p.D342G | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV101511757; called by muse, mutect2, varscan2
- RTTN | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs1334645585, COSV55345216, COSV99733295; called by muse, mutect2, varscan2
- RYR1 | c.14206G>A p.E4736K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV62102932; called by muse, mutect2, varscan2
- SEC22A | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100007102; called by muse, mutect2, varscan2
- SEMA6D | c.2060G>A p.R687Q (on ENST00000316364 / NM_153618.2; = p.R625Q on NM_020858.2) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.892); catalogued as rs370361613; called by muse, mutect2, varscan2
- SNTG1 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52425359; called by muse, mutect2, varscan2
- SPHK2 | c.1964G>C p.*655Sext*2 | Nonstop Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99709489; called by muse, mutect2, varscan2
- SPTLC2 | c.1413G>C p.L471F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99377770; called by muse, mutect2, varscan2
- SYNE2 | c.12778G>C p.E4260Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as rs780016741, COSV100648210; called by muse, mutect2, varscan2
- TAF1C | c.32T>G p.L11W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100499738; called by muse, mutect2, varscan2
- TBRG4 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as COSV99345556; called by muse, mutect2, varscan2
- TMEM63A | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834429; called by muse, mutect2, varscan2
- TNK2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760128364, COSV100361551; called by muse, mutect2, varscan2
- TRIM46 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV99826037; called by muse, mutect2, varscan2
- TSC22D1 | c.2860C>A p.P954T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV101488149; called by muse, mutect2, varscan2
- TXK | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99972678; called by muse, mutect2, varscan2
- URB2 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.293); catalogued as rs747838556, COSV99271628; called by muse, mutect2, varscan2
- USH2A | c.3754C>G p.Q1252E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs191540138, COSV100239377; called by muse, mutect2, varscan2
- VCPKMT | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); catalogued as COSV53569046, COSV99366537; called by muse, mutect2, varscan2
- VWF | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760061887, COSV54632567, COSV99779710; called by muse, mutect2, varscan2
- WDR72 | c.3253G>C p.G1085R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100854914; called by muse, mutect2, varscan2
- ZFAT | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 116/210 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763648740, COSV64742176; called by muse, varscan2
- ZNF221 | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV99240868; called by muse, mutect2, varscan2
- ARID1A | c.2471_2511del p.P824Rfs*34 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- FCGBP | c.12556C>T p.Q4186* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- NHEJ1 | c.217_219del p.L73del | In Frame Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- OR8J1 | c.489_497del p.F164_V166del | In Frame Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- PC | c.3418_3435del p.L1140_M1145del | In Frame Del (DEL) | VAF 17/179 reads (9%) | called by mutect2, pindel
- PTDSS1 | c.909_923del p.N303_L307del | In Frame Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel
- ADGRG2 | c.1593G>C p.L531= (on ENST00000379869 / NM_001079858.3; = p.L528= on NM_005756.4) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs754392947, COSV100492497, COSV100492779; called by muse, mutect2, varscan2
- ADPRHL1 | c.528G>A p.T176= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs559793322, COSV100733505; called by muse, mutect2, varscan2
- ARHGAP32 | c.4749G>A p.V1583= (on ENST00000310343 / NM_001378025.1; = p.V1234= on NM_014715.4) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100088595; called by muse, mutect2, varscan2
- ARID1A | c.4719G>A p.Q1573= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs761906554, COSV100252677; called by muse, mutect2
- BRCA2 | c.687G>T p.V229= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV101204524; called by muse, varscan2
- BRICD5 | c.708G>C p.L236= (on ENST00000562360; = p.L204= on NM_182563.3) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57031110; called by muse, mutect2, varscan2
- CARMIL2 | c.441G>A p.E147= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100576177; called by muse, mutect2, varscan2
- CFAP58 | c.1965C>G p.L655= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100866131, COSV63836845; called by muse, mutect2, varscan2
- CLASP1 | c.606G>C p.V202= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99756313; called by muse, mutect2, varscan2
- CLPTM1L | c.183G>A p.T61= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100307241; called by muse, mutect2, varscan2
- DMWD | c.1224G>A p.A408= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs747273351, COSV99353504; called by muse, mutect2, varscan2
- DRAP1 | c.180G>A p.R60= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV56988310, COSV56989657, COSV56989722; called by muse, mutect2
- HADHA | c.1788G>A p.A596= | Silent (SNP) | VAF 50/174 reads (29%) | catalogued as rs190409957, COSV101024089; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HDAC4 | c.994A>C p.R332= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100613968; called by muse, mutect2, varscan2
- HOXA1 | c.537C>G p.S179= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV99761340, COSV99761409; called by muse, mutect2, varscan2
- LYRM1 | c.279C>A p.T93= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99533972; called by muse, mutect2, varscan2
- MARCHF6 | c.1836C>T p.L612= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99930024; called by muse, mutect2, varscan2
- MME | c.2205C>T p.C735= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV100852482; called by muse, mutect2, varscan2
- P2RY1 | c.45T>G p.A15= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV100521753; called by muse, mutect2, varscan2
- PCDHB12 | c.1404G>A p.L468= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV99507596; called by muse, mutect2, varscan2
- PREX1 | c.822G>T p.L274= | Silent (SNP) | VAF 40/195 reads (21%) | catalogued as COSV100906630; called by muse, mutect2, varscan2
- PTP4A3 | c.489A>T p.P163= (on ENST00000329397; = p.P138= on NM_007079.3) | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100267385; called by muse, mutect2, varscan2
- SGMS2 | c.132C>T p.S44= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100763496; called by muse, mutect2, varscan2
- SPEG | c.6540G>C p.R2180= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100405189, COSV100405490; called by muse, mutect2, varscan2
- TSKS | c.876C>T p.P292= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99883534; called by muse, mutect2, varscan2
- UGGT2 | c.634C>T p.L212= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1280114123, COSV65025716, COSV65026073; called by muse, mutect2, varscan2
- CCDC142 | c.-2C>T | 5'UTR (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99282294; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559099 T>C | 5'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
